Somatic mutation profile of tumor specimen TCGA-AG-3575-01A (aliquot TCGA-AG-3575-01A-01D-1989-10) from TCGA case TCGA-AG-3575, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 51.8 years (18,932 days).
Specimen TCGA-AG-3575-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acea3642-37db-4528-ad16-6db09c0788c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3575-10A (Blood Derived Normal), aliquot TCGA-AG-3575-10A-01D-1989-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b87bb9b-82bf-45a0-8658-55042939de14

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 13, Silent 6, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAHD1 | c.1658C>T p.S553F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV69083681; called by muse, mutect2, varscan2
- CNMD | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 88/125 reads (70%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV65032282; called by muse, mutect2, varscan2
- ENTPD8 | c.1335G>A p.M445I (on ENST00000371506 / NM_001033113.2; = p.M408I on NM_198585.3) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100395692; called by muse, mutect2, varscan2
- FAT4 | c.1513G>A p.G505S | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101272656; called by muse, mutect2, varscan2
- HECW1 | c.3830G>A p.R1277Q | Missense Mutation (SNP) | VAF 83/278 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs150833111, COSV67833322; called by muse, mutect2, varscan2
- IGFBP5 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99289064; called by muse, mutect2, varscan2
- KIDINS220 | c.3499A>T p.S1167C | Missense Mutation (SNP) | VAF 76/231 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99876327; called by muse, mutect2, varscan2
- LRRK1 | c.2585G>A p.S862N | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV99442721; called by muse, mutect2, varscan2
- MINDY2 | c.1737G>A p.Q579= | Splice Region (SNP) | VAF 35/94 reads (37%) | catalogued as rs759412691, COSV100376564; called by muse, mutect2, varscan2
- OR6B1 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 70/191 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.018); catalogued as rs374206359, COSV68769859; called by muse, mutect2, varscan2
- SPTA1 | c.3623C>A p.A1208D | Missense Mutation (SNP) | VAF 155/384 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.315); catalogued as COSV100935461; called by muse, varscan2
- SPTLC3 | c.338T>G p.F113C | Missense Mutation (SNP) | VAF 106/268 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100983276; called by muse, mutect2, varscan2
- SSBP4 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1384340671, COSV99526286; called by muse, mutect2, varscan2
- TSSK6 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.448); catalogued as rs1346439605, COSV53062759; called by muse, mutect2, varscan2
- MPP3 | c.1650C>T p.D550= | Silent (SNP) | VAF 89/408 reads (22%) | catalogued as rs369690455, COSV68199067; called by muse, varscan2
- NAV3 | c.2559G>T p.L853= | Silent (SNP) | VAF 80/222 reads (36%) | catalogued as COSV99894800; called by mutect2, varscan2
- PARP6 | c.1275C>T p.N425= | Silent (SNP) | VAF 112/312 reads (36%) | catalogued as COSV99536342; called by muse, mutect2, varscan2
- RFNG | c.696G>A p.V232= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV57650733; called by muse, mutect2, varscan2
- SNAPC2 | c.954G>A p.P318= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs201014690, COSV54490713; called by muse, mutect2, varscan2
- VASN | c.1596C>T p.S532= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as rs375299971, COSV99228225; called by muse, mutect2, varscan2
